Somatic mutation profile of tumor specimen TCGA-VS-A9V3-01A (aliquot TCGA-VS-A9V3-01A-11D-A42O-09) from TCGA case TCGA-VS-A9V3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 62.9 years (22,990 days).
Specimen TCGA-VS-A9V3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84683acf-7277-452f-a9a3-e2df65f67bcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9V3-10A (Blood Derived Normal), aliquot TCGA-VS-A9V3-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70b0a5cf-6731-41c3-b312-184816e5a583

The open-access MAF lists 182 somatic variants for this specimen: 132 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 47, Nonsense Mutation 11, Frame Shift Del 7, Splice Site 3, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as rs146816935, COSV52281654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 60/135 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.1216-1G>T p.X406_splice | Splice Site (SNP) | VAF 40/102 reads (39%) | hotspot (GDC flag); catalogued as CS971888, COSV57295479, COSV57298451, COSV57332521; called by muse, mutect2, varscan2
- ABCG1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs781438237, COSV100494517; called by muse, mutect2, varscan2
- AGAP2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs1027210475, COSV99224236; called by muse, mutect2, varscan2
- AGAP2 | c.632C>A p.S211* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99224238; called by muse, mutect2, varscan2
- ALK | c.3409G>A p.G1137R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762571775, COSV66595325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.2674G>C p.E892Q (on ENST00000392977 / NM_001286615.2; = p.E857Q on NM_178826.4) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100153135, COSV100153802; called by muse, mutect2, varscan2
- ANOS1 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99391071; called by muse, mutect2, varscan2
- ARPP21 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.075); catalogued as COSV99490727; called by muse, mutect2, varscan2
- ASB3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99712513; called by muse, mutect2, varscan2
- BCAT2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV60273709; called by muse, mutect2, varscan2
- BCORL1 | c.2715C>A p.N905K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1301926252, COSV99500909; called by muse, mutect2, varscan2
- BRIP1 | c.3386C>G p.S1129C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.386); catalogued as COSV99369113, COSV99371073; called by muse, mutect2
- C21orf62 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs781073580, COSV66671926; called by muse, mutect2, varscan2
- C2CD6 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV99634626; called by muse, mutect2
- CACNA2D4 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as COSV99766487; called by muse, mutect2, varscan2
- CAPN9 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681116; called by muse, mutect2, varscan2
- CHST5 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.416); catalogued as rs745623278, COSV100292131; called by muse, varscan2
- CIAPIN1 | c.729G>T p.R243S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV101275930; called by muse, mutect2, varscan2
- CIPC | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747608007, COSV62377423; called by muse, mutect2, varscan2
- CLASP2 | c.2980C>T p.Q994* (on ENST00000359576; = p.Q993* on NM_015097.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100224255; called by muse, mutect2, varscan2
- COL1A1 | c.2034G>C p.E678D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.813); catalogued as rs147483404; called by mutect2, varscan2
- CPD | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.95); catalogued as rs371151229, COSV99853283; called by muse, mutect2, varscan2
- CPT1A | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778008039, COSV55755437; called by muse, mutect2, varscan2
- CSF1R | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV99643036; called by muse, mutect2, varscan2
- CUX2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs751335439, COSV99920726; called by muse, mutect2, varscan2
- DDX31 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99707711; called by muse, mutect2, varscan2
- EP300 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV54339708, COSV99609302; called by muse, mutect2, varscan2
- EPS15 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.616); catalogued as COSV100869606; called by muse, mutect2, varscan2
- EPS15 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.28); catalogued as COSV100869607; called by muse, mutect2, varscan2
- EXOC7 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100135768; called by muse, mutect2, varscan2
- FADS3 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.069); catalogued as rs1290183689, COSV99605507; called by muse, mutect2, varscan2
- FANCM | c.3775C>G p.L1259V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99951630; called by muse, mutect2, varscan2
- FGFR2 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CD061416, COSV60642940; called by muse, mutect2, varscan2
- GIN1 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV101204418; called by muse, mutect2
- GLB1L | c.1470C>A p.F490L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99850904; called by muse, mutect2, varscan2
- GPSM1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 110/180 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs1387911299, COSV100696684; called by muse, mutect2, varscan2
- GRIP2 | c.2303C>T p.S768L (on ENST00000619221; = p.S671L on NM_001080423.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1308275100, COSV99817658; called by muse, mutect2
- GRM5 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs1439046675, COSV59637096; called by muse, mutect2, varscan2
- HACD3 | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56012093; called by muse, mutect2, varscan2
- HAUS6 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs773167853, COSV100997908; called by muse, mutect2
- HMMR | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV100701025, COSV100701055; called by muse, mutect2, varscan2
- HSPA8 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV99914624; called by muse, mutect2, varscan2
- IL5RA | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as COSV99843323; called by muse, mutect2, varscan2
- ILK | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV54990736; called by muse, mutect2, varscan2
- IRS4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100929731; called by muse, mutect2, varscan2
- JPH2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); catalogued as COSV65902947, COSV65905090; called by muse, mutect2, varscan2
- KCNB2 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101579007, COSV73052733; called by muse, mutect2, varscan2
- KMT2C | c.6973C>T p.Q2325* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV51501752; called by muse, mutect2, varscan2
- KNTC1 | c.4345G>C p.E1449Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV100338808; called by muse, mutect2, varscan2
- KRT73 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59838000; called by muse, mutect2, varscan2
- L2HGDH | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.627); catalogued as COSV99910367, COSV99910559; called by muse, mutect2, varscan2
- LEPR | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100756741; called by muse, mutect2, varscan2
- LIN37 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50000795, COSV99137508; called by muse, varscan2
- LRP4 | c.3947G>T p.R1316I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV101066886; called by muse, mutect2, varscan2
- MAML3 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101558526; called by muse, mutect2, varscan2
- MAPK14 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV100005195; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100825221; called by muse, mutect2
- MPP2 | c.1339G>A p.E447K (on ENST00000461854 / NM_001278372.2; = p.E423K on NM_005374.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs987126243, COSV99290820; called by muse, mutect2, varscan2
- MTUS2 | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV101462367, COSV70916537; called by muse, varscan2
- NHS | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.121); catalogued as COSV101196987; called by muse, mutect2, varscan2
- NTN1 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV51480552; called by muse, mutect2, varscan2
- OR10H2 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV100008886; called by muse, mutect2, varscan2
- OR2J2 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs201438710; called by muse, mutect2, varscan2
- OTULIN | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.347); catalogued as COSV99420047; called by muse, mutect2, varscan2
- PAG1 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99597910; called by muse, mutect2, varscan2
- PAWR | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60922880; called by muse, mutect2, varscan2
- PCDH11X | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015250, COSV53483709; called by muse, mutect2, varscan2
- PCDHA1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100974485; called by muse, mutect2, varscan2
- PIDD1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV100758782; called by muse, mutect2
- PIWIL4 | c.1258A>G p.N420D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1325717734, COSV100133429; called by muse, mutect2, varscan2
- PJA1 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.202); catalogued as COSV100824812; called by muse, mutect2
- PKP3 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV58989967; called by muse, mutect2, varscan2
- PMPCB | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs951007403, COSV99971441; called by muse, mutect2, varscan2
- POU6F1 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs771763739, COSV61327900; called by mutect2, varscan2
- PRDM5 | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs754024988, COSV99311404; called by muse, mutect2, varscan2
- PROZ | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV61439717; called by muse, mutect2, varscan2
- PTPRZ1 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV66444474; called by muse, mutect2, varscan2
- QSER1 | c.2581G>A p.A861T (on ENST00000399302; = p.A990T on NM_001076786.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101234966; called by muse, mutect2, varscan2
- RBBP5 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV52705570; called by muse, mutect2, varscan2
- RELA | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.467); catalogued as rs1172744425, COSV100425940, COSV58015651; called by muse, mutect2, varscan2
- RILPL2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1367873672, COSV99760304; called by muse, mutect2, varscan2
- RIPOR3 | c.110+1G>A p.X37_splice | Splice Site (SNP) | VAF 96/164 reads (59%) | catalogued as rs778793897, COSV99246029; called by muse, mutect2, varscan2
- RNF148 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs777129168, COSV57365043; called by muse, mutect2, varscan2
- RPL13 | c.477+1G>C p.X159_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99245429; called by muse, mutect2, varscan2
- RTP4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745497502, COSV99372372; called by muse, mutect2, varscan2
- SEMA4B | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.105); catalogued as COSV100203275; called by muse, mutect2, varscan2
- SERPINB8 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs549578248, COSV54639945; called by muse, mutect2, varscan2
- SLC24A2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99647458; called by muse, mutect2, varscan2
- SLC25A6 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV101195507, COSV67317875; called by muse, mutect2, varscan2
- SLC28A3 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.359); catalogued as COSV100883301, COSV100883341; called by muse, mutect2, varscan2
- SLC2A5 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101072694; called by mutect2, varscan2
- SLC34A2 | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV65941643; called by muse, mutect2, varscan2
- SMARCAD1 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs768385881, COSV100758974, COSV62773721; called by muse, mutect2, varscan2
- SORBS1 | c.2080C>T p.Q694* (on ENST00000361941 / NM_001034954.2; = p.Q400* on NM_006434.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99528914; called by muse, mutect2
- SORCS1 | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.099); catalogued as COSV99550287; called by muse, mutect2, varscan2
- SPEF2 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV56799781, COSV99214211; called by muse, mutect2, varscan2
- SPG11 | c.6567G>T p.M2189I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV99969627; called by muse, mutect2, varscan2
- STT3B | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55501145; called by muse, mutect2, varscan2
- SYCP2L | c.2030C>A p.S677* | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as COSV99305843; called by muse, mutect2, varscan2
- TCF12 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as rs201017357, COSV99978944; called by muse, mutect2, varscan2
- TMED6 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as rs202173115, COSV99650917; called by muse, mutect2
- TMEM248 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV100447483; called by muse, mutect2, varscan2
- TMEM72 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV101273599; called by muse, mutect2
- TMTC1 | c.2144C>G p.S715C (on ENST00000539277 / NM_001193451.2; = p.S607C on NM_175861.3) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV99760996; called by muse, mutect2, varscan2
- TPO | c.2071C>G p.L691V | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760491353, COSV100222091, COSV61100147; called by muse, mutect2, varscan2
- TREML1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100632705, COSV58294611; called by muse, mutect2, varscan2
- TRIP10 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV100505308; called by muse, mutect2, varscan2
- TSEN15 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.031); catalogued as COSV100837368; called by muse, mutect2, varscan2
- UBAP2 | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs144480091; called by muse, mutect2, varscan2
- UBR4 | c.3012G>C p.L1004F | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV100921861; called by muse, mutect2, varscan2
- WAPL | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.018); catalogued as COSV100077263; called by muse, mutect2, varscan2
- WIPF1 | c.420del p.S142Hfs*99 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV99769257; called by mutect2, pindel, varscan2
- WWP2 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV100598767; called by muse, mutect2, varscan2
- WWP2 | c.2544G>T p.K848N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100598769; called by muse, mutect2, varscan2
- ZHX3 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100476728; called by muse, varscan2
- ZNF253 | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV100849594, COSV63038077; called by muse, mutect2, varscan2
- ZNF384 | c.1570C>G p.P524A (on ENST00000361959; = p.P463A on NM_133476.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100158882; called by muse, mutect2, varscan2
- ZNF407 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99996744; called by muse, mutect2, varscan2
- ZNF548 | c.1075C>G p.H359D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs756598225, COSV100278291; called by muse, mutect2, varscan2
- ZNF687 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1298060342, COSV99650154; called by muse, mutect2, varscan2
- ZNF780A | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as COSV100575242; called by muse, mutect2
- ZSCAN10 | c.580G>A p.E194K (on ENST00000252463; = p.E249K on NM_032805.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV99373832; called by muse, mutect2, varscan2
- BOP1 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL6A5 | c.6753del p.D2252Ifs*45 (on ENST00000312481; = p.D2248Ifs*45 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- EDC3 | c.839del p.P280Qfs*20 | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel, varscan2
- IGLV4-60 | c.280del p.A94Lfs*? | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- LATS1 | c.2085del p.R697Gfs*10 | Frame Shift Del (DEL) | VAF 32/62 reads (52%) | called by mutect2, pindel, varscan2
- RB1 | c.1950_1951del p.F650Lfs*2 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- STK11 | c.1000_1040del p.S334Gfs*12 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- TRBJ2-3 | chr7:142796891 del GCTCGG | Missense Mutation (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- ABHD3 | c.189G>A p.E63= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV56677104; called by muse, mutect2, varscan2
- ARL11 | c.12G>A p.V4= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99949183; called by muse, mutect2
- CARD6 | c.1887C>G p.L629= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99621302; called by muse, mutect2, varscan2
- CSMD3 | c.8601C>G p.L2867= (on ENST00000297405 / NM_001363185.1; = p.L2698= on NM_052900.3) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs773603250, COSV52166783, COSV52188131, COSV52190075; called by muse, mutect2, varscan2
- DDIT4L | c.165G>A p.Q55= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99913982; called by muse, mutect2, varscan2
- DDX55 | c.1779C>T p.I593= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99434836; called by muse, mutect2
- DEFB4A | c.36C>T p.F12= | Silent (SNP) | VAF 43/272 reads (16%) | catalogued as rs1323737122, COSV100156655; called by muse, mutect2, varscan2
- DENND4C | c.2175G>A p.L725= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV100991560, COSV66822873; called by muse, mutect2, varscan2
- DOK1 | c.81C>T p.A27= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99284203; called by muse, varscan2
- DOT1L | c.4071C>T p.R1357= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs776955895, COSV101288724; called by muse, mutect2, varscan2
- DSCAML1 | c.1296C>A p.L432= (on ENST00000321322; = p.L372= on NM_020693.4) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV58399194; called by muse, mutect2, varscan2
- EDAR | c.990C>T p.L330= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs751322328, COSV99304280; called by muse, mutect2, varscan2
- EXOC7 | c.294G>A p.E98= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100135765; called by muse, varscan2
- FIS1 | c.165C>T p.I55= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs750618988, COSV99778972; called by muse, mutect2, varscan2
- FOXP2 | c.1737A>G p.E579= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100647392; called by muse, mutect2, varscan2
- GLB1L | c.1872C>T p.L624= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99850900; called by muse, mutect2, varscan2
- GLP2R | c.135C>T p.L45= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99302483, COSV99302489; called by muse, mutect2
- GNAO1 | c.735C>T p.H245= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs201930720, COSV52617906; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIA3 | c.2415C>T p.C805= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV52052447; called by muse, mutect2, varscan2
- GTF3C1 | c.657C>T p.N219= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs572465496, COSV62246577; called by muse, mutect2, varscan2
- KAT6A | c.2133C>T p.I711= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99705883; called by muse, mutect2, varscan2
- KRTAP26-1 | c.375G>A p.L125= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100860485; called by muse, mutect2, varscan2
- MAGEC3 | c.1512C>T p.F504= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV68924311; called by muse, mutect2, varscan2
- MTUS2 | c.3057G>A p.L1019= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1202329350, COSV70913426; called by muse, varscan2
- NACC2 | c.318C>T p.F106= | Silent (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- NR5A1 | c.786C>T p.F262= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs566939634, COSV65294595; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2A2 | c.336G>A p.L112= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV101286634; called by muse, mutect2, varscan2
- OR2A2 | c.423G>A p.T141= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs761421065, COSV68871667; called by muse, mutect2, varscan2
- OXCT2 | c.1371G>A p.L457= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100560388; called by muse, mutect2, varscan2
- PCYOX1 | c.618C>T p.A206= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs186275811, COSV52478867; called by muse, mutect2, varscan2
- PDGFRA | c.897C>G p.V299= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99957628; called by muse, mutect2
- PIGT | c.576C>T p.L192= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99649218; called by muse, mutect2, varscan2
- PLD4 | c.1473C>T p.V491= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- RASGRP4 | c.978C>T p.L326= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1457659734, COSV99498823; called by muse, mutect2, varscan2
- RBBP9 | c.546G>A p.L182= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100464185; called by muse, mutect2, varscan2
- RIC3 | c.984T>C p.P328= (on ENST00000309737 / NM_001206671.4; = p.P327= on NM_024557.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100112357; called by muse, mutect2, varscan2
- RNF44 | c.900C>T p.Y300= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99222000; called by muse, mutect2
- RNH1 | c.360C>T p.L120= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs762414066, COSV100596871; called by muse, mutect2, varscan2
- RPUSD2 | c.597C>T p.I199= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100225281; called by muse, mutect2, varscan2
- SDCCAG8 | c.2106G>A p.R702= | Silent (SNP) | VAF 31/44 reads (70%) | catalogued as rs1201454177, COSV100286854; called by muse, mutect2, varscan2
- SELE | c.1050C>A p.T350= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100325136; called by mutect2, varscan2
- SEMA4B | c.1221G>A p.R407= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100153433; called by muse, mutect2, varscan2
- SEPTIN9 | c.375C>T p.I125= (on ENST00000427177 / NM_001113491.2; = p.I107= on NM_006640.4) | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs573465338, COSV61203709; called by muse, mutect2, varscan2
- TIMM22 | c.195G>T p.A65= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100508314; called by muse, mutect2, varscan2
- TRMT10C | c.246C>T p.I82= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV59305349; called by muse, mutect2, varscan2
- VN1R2 | c.726G>A p.K242= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs1467321179, COSV100448174; called by muse, mutect2, varscan2
- ZYG11B | c.294C>T p.F98= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV53758135; called by muse, mutect2, varscan2
- OSGIN1 | n.2048G>C | RNA (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100534139; called by muse, mutect2, varscan2
- PKD1L2 | n.1105G>A | RNA (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- PRSS38 | c.-1C>T | 5'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64540441; called by muse, mutect2, varscan2
